Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A2IZ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A2IZ-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Specimens Submitted:

1: SP: Retroperitoneal sarcoma with right kidney

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEUM AND RIGHT KIDNEY, EXCISION:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA.
- TUMOR SIZE: 29.0 CM IN GREATEST DIMENSION.
- TUMOR INVOLVES SOFT TISSUE AND SHOWS FOCAL MINIMAL INVASION INTO RENAL CORTEX.
- THE DEDIFFERENTIATED COMPONENT HAS A HIGH GRADE UNDIFFERENTIATED APPEARANCE AND SHOWS EXTENSIVE AREAS OF NECROSIS (GROSSLY ESTIMATED AS 60%).
- THE WELL-DIFFERENTIATED COMPONENT EXTENDS TO THE MEDIAL MARGIN AND IS < 0.1 CM FROM PROXIMAL AND INFERIOR MARGINS.
- THE DEDIFFERENTIATED COMPONENT < 0.1 CM FROM THE SUPERIOR AND MEDIAL MARGINS.
- ADDITIONAL MARGINS ARE WIDELY FREE OF TUMOR.
- ADRENAL GLAND AND KIDNEY PARENCHYMA ARE UNREMARKABLE.
- RENAL VESSELS ARE FREE OF TUMOR.
- IMMUNOSTAINS ARE NEGATIVE FOR S100, CAM5.2 AND AE1/AE3.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON THE PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) BY THE PATHOLOGIST WHOSE NAME APPEARS ABOVE MINE, AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***
Signed out by () M.D.

Special Studies:

Result	Special Stain	Comment
	S-100	
	AE1:AE3	
	CAM 5.2	
	IMM RECUT	
	NEG CONT	

** Continued on next page **

1CD-0-3

dedifferentiated liposarcoma

8858/3

Site: retroperitoneum C48.0

hw 7/24/11

[page 2 of 3]
Gross Description:
M.D.

1). The specimen is received fresh, labeled "retroperitoneal sarcoma with right kidney" and consists of a soft tissue mass measuring 29.0 cm lateral to medial, 16.0 cm anterior to posterior and 14.0 cm superior to inferior. A distorted adrenal gland is identified on the superior aspect of the specimen measuring 7.0 x 3.0 x 0.6 cm. The specimen is inked blue-superior, red-inferior, black-posterior, green-anterior, yellow-medial and orange-lateral and bisected to reveal a grossly unremarkable 12.0 x 7.0 x 2.5 cm kidney compressed and surrounded by a poorly circumscribed white to tan rubbery glistening mass measuring 16.5 x 13.5 x 8.5 cm mainly on the inferior posterior and lateral aspect and a second measuring 12.5 x 8.5 x 13.5 cm fairly circumscribed light tan, soft with approximately 60% necrotic with hemorrhagic areas mass on the superior medial aspect at the hilum level compressing but not involving the kidney. The tumors about the superior, inferior, medial and posterior margins and is located 1.5 cm from the anterior and 7.0 cm from the lateral margin. The tumors represents approximately 80% of the specimen and grossly infiltrate the surrounding adipose tissue. The specimen is photographed. TPS is taken. Representative sections of the tumor, adrenal gland, kidney, and all perpendicular margins are submitted.

Summary of sections:

AM-anterior green margin
PM-posterior black margin
MM-medial yellow margin
LM-lateral orange margin
SM-superior blue margin
IM-inferior red margin
KLT-kidney to lateral tumor
KMT-kidney to medial tumor
KM-kidney ureter and vessel margins
AG-adrenal gland
TI-tumor interface
LT-lateral tumor
MT-medial tumor

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma with right kidney

Block	Sect.	Site	PCs
1		ag	1
1		am	1
1		im	1

** Continued on next page **

[page 3 of 3]
2	klt	2
1	kcm	1
2	kmt	2
1	lm	1
2	lt	2
1	mm	1
2	mt	2
1	pm	1
1	sm	1
2	ti	2

** End of Report **

Source: NCI Genomic Data Commons file b3a5fb77-e9cc-413e-b7fb-473aa2d18026 (TCGA-DX-A2IZ.55C7285D-2A4F-45F6-BD7F-87FEBB5CC039.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).